Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RO, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RO-01A (Primary Tumor).

Nature of material: Brain

Received on:

Macroscopy:

Received two irregular pieces of gelatinous, brown and blackish tissue, with areas of bleeding permeated, measuring 4.6 x 3.3 x 2.4 cm and weighing 7.0 g.

Microscopy:

Histological sections stained with H & E shows sections of moderately cellular neuroglial neoplasm formed by neoplastic component of astrocytic phenotype adjacent to a component of neoplastic cells with oligodendroglial phenotype. Detected 1 figure of mitosis in 10 HPF. The vascular network is branched, but does not show areas of microvascular proliferation. There are rare foci of dystrophic microcalcifications. There are no areas of necrosis.

Diagnosis:

Biopsy product of lesions in the left frontal lobe:

- Oligoastrocitoma, grade II (WHO). ICD-O: 9382/3.

Immunohistochemical examination results:

- GFAP: POSITIVE in neoplasia.

- Bcl-2: POSITIVE in neoplasia.

- P53: POSITIVE in neoplasia.

Galectin-3: NEGATIVE in neoplasia.

CONCLUSION: Oligoastrocitoma grade II (WHO).

PROFESSIONAL PARTICIPANTS OF REPORT

ICD-O-3
Oligoastrocytoma, grade II
9382/3
Site Brain, supratentorial
path
① Brain, frontal lobe
JW 10/4/13

Source: NCI Genomic Data Commons file 2e255374-6ae4-4180-b4fe-0d54fd2ed859 (TCGA-TQ-A7RO.41735167-9814-4D95-A3D4-E1C0B8575C9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).